Gene-level copy-number profile of tumor specimen HCM-BROD-0701-C43-06B from HCMI case HCM-BROD-0701-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.1 years (27,073 days).
Specimen HCM-BROD-0701-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1091757-3a70-4d98-a6b0-221e51203fd4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0701-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/646180ef-43de-4976-a299-86405eea15d1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 1; copy number 2: 283; copy number 3: 8,821; copy number 4: 25,147; copy number 5: 10,885; copy number 6: 7,201; copy number 7: 2,520; copy number 8: 1,344; copy number 9: 1,995; copy number 10: 55; copy number 12: 71; copy number 13: 52.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,956,444, 28 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,173 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,402,724–152,445,456, 52 genes, copy number 9: POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN, FLG-AS1, AL589986.2, HRNR, FLG, FLG2, HMGN3P1, CRNN.
- chr1:153,259,687–163,321,791, 455 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:164,343,005–166,167,001, 39 genes, copy number 9 (within-gene range 4–9): NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1.
- chr1:166,165,911–170,739,421, 104 genes, copy number 9 (broad region; genes not listed).
- chr4:48,932,755–49,062,081, 4 genes, copy number 9: RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:51,843,000–54,976,371, 55 genes, copy number 10–13: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3.
- chr7:73,699,206–75,416,787, 55 genes, copy number 9 (within-gene range 6–9): STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1.
- chr7:79,452,877–79,654,227, 3 genes, copy number 9 (within-gene range 6–9): MAGI2-AS3, NUP35P2, RNA5SP234.
- chr7:79,912,104–79,912,208, 1 gene, copy number 9: RNU6-849P.
- chr14:21,521,080–28,490,362, 308 genes, copy number 9 (broad region; genes not listed).
- chr14:29,576,479–30,191,898, 1 gene, copy number 9 (within-gene range 7–9): PRKD1.
- chr14:29,928,445–34,876,459, 80 genes, copy number 9–10 (broad region; genes not listed).
- chr17:49,887,598–83,240,804, 988 genes, copy number 9–12 (broad region; genes not listed).
- chr20:48,324,812–49,568,137, 28 genes, copy number 13: AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
